Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HS, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HS-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M
Reported:
Submitting Physicians:
Pathologist:
Intraop Pathologist:
Performing Physician:

Service:

Received:

TRD-0-3
myxoid Leiomyosarcoma 8896/3
Site: Retroperitoneum
C48.0
JW 4/22/14

CLINICAL HISTORY:
NONE GIVEN.

PREOPERATIVE DIAGNOSIS:
RETROPERITONEAL SARCOMA.

SPECIMEN TYPE(S):
A: RETROPERITONEAL SARCOMA (FS)
B: RETROPERITONEAL SARCOMA
C: TRANSVERSE COLON TUMOR (PERM)

Amendment
Amended:
Reason: This amendment is being issued to correct the collect date of the specimen so that it appears in the correct location in . There is no patient care impact.
Previous Signout Date:

FINAL DIAGNOSIS:
A. RETROPERITONEAL SARCOMA:
Dedifferentiated liposarcoma. See comment.
Tumor size: 3.5 cm.
5% tumor necrosis.
B. RETROPERITONEAL SARCOMA:
Dedifferentiated liposarcoma. See comment.
Tumor size: 30.0 cm.
30% tumor necrosis.
C. TRANSVERSE COLON TUMOR:
Dedifferentiated liposarcoma. See comment.
Tumor size: 8.0 cm.
5% tumor necrosis.

COMMENT: The dedifferentiated component is high-grade myxoid leiomyosarcoma.

NOTE: Immunoperoxidase stains are performed with appropriate positive and negative controls on block B5. The neoplastic cells are positive for vimentin, desmin and actin, and negative for smooth muscle myosin, S100, CD117, CD99, CD34, CD10. Ki-67 shows 15-25% nuclear positivity. The immunoreactivity supports the diagnosis.

INTRADEPARTMENTAL CONSULTATION:

reportable

I, , M.D. the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically signed out by

[page 2 of 2]
OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:

- A. RETROPERITONEAL SARCOMA (FS):
Sarcoma, defer to permanent sections.

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by
Dr. in OR.

I, MD, have performed the intraoperative consultation(s) and issued
the above diagnoses.

GROSS DESCRIPTION:

- A. Specimen is received fresh labeled, "retroperitoneal sarcoma". The specimen consists of a multilobulated, yellow-tan fragment of soft tissue measuring 3.5 x 3.5 x 3.0 cm. The specimen is serially sectioned to reveal a tan-white to tan-pink cut surface with mucinous aspect. There are areas of necrosis present (5%). Representative fresh tissue is submitted for frozen section evaluation as FSA1. Representative fresh tissue is submitted to the Representative sections are submitted as A1-A8.
- B. Specimen is received fresh labeled, "retroperitoneal sarcoma". The specimen consists of a 2,861.0-g, 30 x 30 x 10-cm multilobulated, tan-white to tan-pink fragment of soft tissue. Extensive areas of necrosis are present (30%). There are areas of mucoid degeneration. There are no areas of cystic degeneration present. Representative fresh tissue is submitted to Representative sections are submitted as B1-B25.
- C. Specimen is received fresh labeled, "transverse colon". The specimen consists of a tan-white to tan-pink, multilobulated mass measuring 8.0 x 6.0 x 5.5 cm. The external surface is smooth. The entire external surface is marked with blue ink. There is not an attached segment of large bowel. The specimen is serially sectioned to reveal a tan yellow cut surface. Areas of necrosis, hemorrhage or cystic degeneration are not grossly identified. Representative fresh tissue is not submitted to Representative sections are submitted as C1-C10.

Source: NCI Genomic Data Commons file 65afe3a2-181d-46f8-9740-83f5a600a499 (TCGA-3B-A9HS.84CB55EA-C1BF-48B6-9EFF-0E5A82DAD417.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).